Somatic mutation profile of tumor specimen TCGA-HI-7168-01A (aliquot TCGA-HI-7168-01A-11D-2114-08) from TCGA case TCGA-HI-7168, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.6 years (22,881 days).
Specimen TCGA-HI-7168-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fedca08f-040f-4502-832e-afde9d1220df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HI-7168-10A (Blood Derived Normal), aliquot TCGA-HI-7168-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c21ab5c-bfb8-4287-b9d1-2fb130905ebb

The open-access MAF lists 47 somatic variants for this specimen: 28 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 16, RNA 2, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 38/133 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101201018, COSV67017411; called by muse, varscan2
- ACTL7B | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753089435, COSV65926997; called by muse, mutect2, varscan2
- CADPS | c.911C>A p.A304E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51886724; called by muse, varscan2
- CD207 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV69652002; called by muse, mutect2, varscan2
- CENPE | c.7749G>T p.E2583D | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV54383137; called by muse, mutect2
- COQ7 | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58981955; called by muse, mutect2, varscan2
- DGKI | c.1035C>A p.S345R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV55956823; called by muse, mutect2, varscan2
- DLL4 | c.1904A>C p.D635A | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as COSV51064606, COSV51069560; called by muse, varscan2
- EPHA3 | c.1727C>A p.A576E | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV60711668; called by muse, mutect2, varscan2
- GALNTL5 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs368842809, COSV67180145; called by muse, mutect2, varscan2
- GTPBP10 | c.926dup p.N309Kfs*37 | Frame Shift Ins (INS) | VAF 25/93 reads (27%) | catalogued as rs745885335; called by mutect2, varscan2
- IQCN | c.987A>G p.I329M | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1482385532, COSV66575077; called by muse, mutect2, varscan2
- LINGO2 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs202210200, COSV58059589; called by muse, mutect2, varscan2
- MKS1 | c.708C>G p.I236M | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.323); catalogued as COSV100439765, COSV58304693; called by muse, mutect2, varscan2
- MYOM1 | c.3547C>T p.R1183* | Nonsense Mutation (SNP) | VAF 8/140 reads (6%) | catalogued as rs369979714; called by muse, mutect2
- NALCN | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.042); catalogued as COSV51943916; called by muse, mutect2, varscan2
- OLFM1 | c.859G>A p.D287N (on ENST00000371793 / NM_001282611.2; = p.D269N on NM_014279.5) | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.977); catalogued as COSV53279387; called by muse, mutect2, varscan2
- OR5L1 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV61734365; called by muse, mutect2, varscan2
- PCDHB9 | c.2368C>A p.P790T | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV53380494; called by muse, mutect2, varscan2
- PGLYRP2 | c.533C>A p.P178Q | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV52995038; called by muse, mutect2
- PRKCA | c.618T>A p.N206K | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV52587751; called by muse, mutect2, varscan2
- RAB37 | c.499G>A p.V167I (on ENST00000392613 / NM_001006638.3; = p.V160I on NM_175738.5) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.079); catalogued as COSV52853773; called by muse, mutect2
- SCNN1B | c.312-1G>T p.X104_splice | Splice Site (SNP) | VAF 10/124 reads (8%) | catalogued as COSV56306376; called by muse, mutect2
- SNW1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 31/405 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55054955; called by muse, mutect2
- TELO2 | c.2113C>T p.Q705* | Nonsense Mutation (SNP) | VAF 11/101 reads (11%) | catalogued as rs756134876, COSV51979012; called by muse, mutect2, varscan2
- TRMT6 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV52544184, COSV99177609; called by muse, mutect2
- USP31 | c.2543C>T p.S848F | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV54853637; called by muse, mutect2, varscan2
- ABCA5 | c.849C>G p.V283= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV67017414; called by muse, varscan2
- ARHGAP28 | c.1917G>T p.P639= (on ENST00000383472 / NM_001366230.1; = p.P480= on NM_001010000.3) | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV51630739, COSV51640319; called by mutect2, varscan2
- CCKAR | c.165C>T p.S55= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs143718810; called by muse, mutect2, varscan2
- FAM126A | c.1128T>C p.S376= | Silent (SNP) | VAF 75/225 reads (33%) | catalogued as COSV69471933; called by muse, mutect2, varscan2
- FAM171A1 | c.1716C>T p.S572= | Silent (SNP) | VAF 57/157 reads (36%) | catalogued as COSV65317059; called by muse, mutect2, varscan2
- FLT4 | c.1941C>T p.H647= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs779623335, COSV56099825; called by muse, mutect2, varscan2
- FREM2 | c.7242C>T p.Y2414= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as rs761762671, COSV54841846; called by muse, mutect2, varscan2
- FUT2 | c.981G>T p.L327= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV67179445; called by muse, mutect2, varscan2
- ITGA2B | c.2112C>A p.I704= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV52233222; called by muse, mutect2, varscan2
- PAQR4 | c.726C>T p.I242= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs570979634, COSV51891767; called by muse, mutect2, varscan2
- PDIA6 | c.900T>A p.A300= | Silent (SNP) | VAF 53/137 reads (39%) | catalogued as COSV55351499; called by muse, mutect2, varscan2
- REV1 | c.1095G>A p.K365= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as COSV51486760; called by muse, mutect2, varscan2
- SPTA1 | c.1623A>G p.K541= | Silent (SNP) | VAF 107/284 reads (38%) | catalogued as rs761453957, COSV63755327; called by muse, mutect2, varscan2
- TNXB | c.6714G>A p.G2238= (on ENST00000647633; = p.G1991= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV64481222; called by muse, mutect2
- UBE2D3 | c.378C>A p.I126= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV57662580; called by muse, mutect2, varscan2
- ZNF33A | c.771T>C p.D257= (on ENST00000458705 / NM_006974.3; = p.D258= on NM_006954.2) | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV56725974; called by muse, mutect2, varscan2
- OFCC1 | n.108A>T | RNA (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2097G>T | Intron (SNP) | VAF 16/65 reads (25%) | catalogued as COSV57630569; called by muse, mutect2, varscan2
- TUBB7P | n.354C>T | RNA (SNP) | VAF 6/31 reads (19%) | catalogued as rs782428150; called by muse, varscan2
